Gene-level copy-number profile of tumor specimen TCGA-AA-A01I-01A from TCGA case TCGA-AA-A01I, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 76.0 years (27,759 days).
Specimen TCGA-AA-A01I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.d5614dfa-5fdf-4b0e-87ce-1234a6cbafa2.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A01I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 400 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/23e55d9a-6d3f-419a-8f04-02b8a80df80b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 28; copy number 2: 46,185; copy number 3: 2,380; copy number 4: 11,440; copy number 5: 75; copy number 6: 105; copy number 7: 5; copy number 9: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A01I-01A-02D-A008-01): tumor purity 0.72, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,183,006–204,183,537, 1 gene: AL592114.2.
- chr7:36,079,084–36,085,736, 1 gene (within-gene range 0–2): AC083864.1.
- chr11:59,358,895–59,371,714, 1 gene (within-gene range 0–2): OR5AN1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 152 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:151,378,003–151,382,381, 2 genes, copy number 5: AC034205.1, AC034205.3.
- chr6:167,975,924–168,101,511, 4 genes, copy number 7: HGC6.3, KIF25-AS1, KIF25, FRMD1.
- chr12:17,479,446–20,753,386, 37 genes, copy number 5–6 (within-gene range 3–6): AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1.
- chr12:109,111,218–109,268,226, 2 genes, copy number 9 (within-gene range 3–9): AC007637.1, ACACB.
- chr14:105,764,503–106,369,546, 104 genes, copy number 6 (broad region; genes not listed).
- chr20:8,998,849–9,481,242, 2 genes, copy number 5 (within-gene range 4–5): Metazoa_SRP, PLCB4.
- chr20:54,859,688–54,859,812, 1 gene, copy number 5: RNU4ATAC7P.

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
